Somatic mutation profile of tumor specimen TCGA-CV-7180-01A (aliquot TCGA-CV-7180-01A-11D-2012-08) from TCGA case TCGA-CV-7180, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 34.3 years (12,523 days).
Specimen TCGA-CV-7180-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de157e24-723c-47bf-820b-fda3a14093f2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7180-10A (Blood Derived Normal), aliquot TCGA-CV-7180-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7451c9b5-b197-4106-b133-b74d3dafce54

The open-access MAF lists 60 somatic variants for this specimen: 43 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 16, Frame Shift Del 2, Splice Region 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 59/215 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as CM970251, COSV100446243, COSV58683273, COSV58688196; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 12/48 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACOT11 | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59347773; called by muse, mutect2, varscan2
- BMP2 | c.389G>T p.R130L | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.668); catalogued as COSV66577064, COSV66578429; called by mutect2, varscan2
- BSN | c.1945G>A p.V649I | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs779715067, COSV56521334; called by muse, mutect2, varscan2
- CARTPT | c.253G>A p.G85S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1240971783, COSV99703927; called by muse, mutect2, varscan2
- CSMD1 | c.10684T>C p.C3562R (on ENST00000520002; = p.C3561R on NM_033225.6) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100145577; called by muse, mutect2, varscan2
- DOCK9 | c.5963A>G p.N1988S (on ENST00000376460 / NM_001366676.2; = p.N1989S on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs757371392, COSV59627474; called by muse, mutect2
- DYDC2 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.386); catalogued as COSV99758033; called by muse, mutect2, varscan2
- EMCN | c.375G>T p.K125N | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV56460646, COSV99598016; called by muse, mutect2, varscan2
- FMR1NB | c.343T>A p.S115T | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.134); catalogued as COSV100789524; called by muse, mutect2, varscan2
- FZR1 | c.262G>A p.G88S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs777457646, COSV100553497; called by muse, mutect2, varscan2
- GPAT2 | c.1915G>T p.A639S | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as COSV100853241, COSV100853359; called by muse, mutect2
- GRK3 | c.1790G>A p.R597Q | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.035); catalogued as rs199620908, COSV60798677; called by muse, mutect2, varscan2
- HELLS | c.1529G>T p.R510L | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99491875; called by muse, mutect2, varscan2
- HTT | c.3527del p.P1176Lfs*3 | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | catalogued as rs1457514406; called by mutect2, varscan2
- L3MBTL4 | c.147G>T p.Q49H | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99531824; called by muse, mutect2
- LGR4 | c.1268A>T p.N423I | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101004048; called by muse, mutect2, varscan2
- LINGO2 | c.1228C>A p.P410T | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs199551773, COSV58056464; called by muse, mutect2, varscan2
- LINGO4 | c.1141T>C p.S381P | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.078); catalogued as COSV100764951; called by muse, mutect2, varscan2
- MED13L | c.5986A>G p.I1996V | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1272594944, COSV99928284; called by muse, mutect2, varscan2
- MNAT1 | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV99709927; called by muse, mutect2
- NEB | c.3570C>T p.N1190= | Splice Region (SNP) | VAF 47/224 reads (21%) | catalogued as rs377168325; called by muse, mutect2, varscan2
- NFYC | c.715A>T p.I239F | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV100438325; called by muse, mutect2, varscan2
- NMS | c.358G>T p.D120Y | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as COSV100966572; called by muse, mutect2, varscan2
- OBSCN | c.7394C>T p.S2465L | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.701); catalogued as COSV99472280; called by muse, mutect2
- OR4D10 | c.347C>T p.S116L | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.189); catalogued as rs773272297, COSV73259969; called by muse, mutect2, varscan2
- PAPPA2 | c.2434G>A p.D812N | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62778463; called by muse, mutect2, varscan2
- PDE4D | c.2414G>A p.R805H (on ENST00000340635 / NM_001104631.2; = p.R669H on NM_006203.4) | Missense Mutation (SNP) | VAF 33/184 reads (18%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs775821294, COSV100401809, COSV57719459; called by muse, mutect2, varscan2
- PLA2R1 | c.2685A>G p.I895M | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.961); catalogued as COSV51781455; called by muse, mutect2, varscan2
- PLEC | c.6799C>G p.Q2267E (on ENST00000322810 / NM_201380.4; = p.Q2157E on NM_000445.5) | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.006); catalogued as COSV100512295; called by muse, mutect2
- PRICKLE4 | c.452C>T p.A151V (on ENST00000359201; = p.A191V on NM_013397.6) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100138668; called by muse, mutect2, varscan2
- PTX4 | c.788C>G p.P263R (on ENST00000447419 / NM_001328608.2; = p.P258R on NM_001013658.1) | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.243); catalogued as COSV99560291; called by muse, mutect2, varscan2
- RTL3 | c.661G>T p.A221S | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as COSV100329642, COSV58185825; called by muse, mutect2, varscan2
- SLC30A6 | c.599C>A p.P200Q | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99249490; called by muse, mutect2, varscan2
- SLC44A1 | c.292T>C p.C98R | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101029157; called by muse, mutect2, varscan2
- SPATA13 | c.1864G>A p.V622I | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs745913840, COSV57975864; called by muse, mutect2, varscan2
- SRGAP1 | c.860C>G p.A287G | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV100754444, COSV61905154; called by muse, mutect2, varscan2
- TBC1D32 | c.3765G>C p.Q1255H | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.8); catalogued as COSV99249849; called by muse, mutect2, varscan2
- TIAM2 | c.235G>A p.G79S | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.005); catalogued as rs768911342, COSV100018352; called by mutect2, varscan2
- ZNF22 | c.110T>C p.I37T | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100026543; called by muse, mutect2, varscan2
- FAM118B | c.877del p.M293Cfs*25 | Frame Shift Del (DEL) | VAF 26/162 reads (16%) | called by mutect2, pindel, varscan2
- FAM193B | c.2362_2372+14del p.X788_splice | Splice Site (DEL) | VAF 6/57 reads (11%) | called by mutect2, pindel
- ACACB | c.6306G>T p.R2102= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV100622572; called by muse, mutect2, varscan2
- ALPK2 | c.6177G>A p.Q2059= | Silent (SNP) | VAF 8/128 reads (6%) | catalogued as COSV100864225; called by muse, mutect2
- CDH18 | c.630C>T p.V210= | Silent (SNP) | VAF 24/97 reads (25%) | catalogued as rs1310964648, COSV56942067; called by muse, mutect2, varscan2
- CFHR2 | c.216C>T p.C72= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs549841110, COSV66380944, COSV66382032; called by muse, mutect2, varscan2
- EIF2B2 | c.180G>T p.L60= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV99837647; called by muse, mutect2, varscan2
- MTHFS | c.177A>G p.Q59= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as rs771059387, COSV99358122; called by muse, mutect2, varscan2
- PCDH12 | c.2460G>A p.P820= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs748934043, COSV99186590; called by muse, mutect2, varscan2
- PHF2 | c.996C>T p.F332= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as COSV63681054; called by muse, mutect2
- PTPRE | c.90C>T p.N30= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs144835853; called by mutect2, varscan2
- SLC30A3 | c.498C>A p.V166= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV99273534; called by muse, mutect2, varscan2
- TICRR | c.4905C>A p.G1635= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as COSV99176104; called by muse, mutect2, varscan2
- TMEM104 | c.603C>T p.P201= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs1317542095, COSV59108688; called by muse, mutect2, varscan2
- VPS50 | c.2832C>T p.I944= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV100004447, COSV100004642; called by muse, mutect2, varscan2
- VPS72 | c.951G>A p.K317= | Silent (SNP) | VAF 8/101 reads (8%) | called by muse, mutect2
- ZMIZ2 | c.495A>T p.T165= | Silent (SNP) | VAF 17/47 reads (36%) | called by muse, mutect2
- ZNF324 | c.1368G>A p.V456= | Silent (SNP) | VAF 23/94 reads (24%) | catalogued as COSV99543182; called by muse, mutect2, varscan2
- CSF2RA | c.*44G>A | 3'UTR (SNP) | VAF 12/164 reads (7%) | catalogued as rs781308302, COSV100817592; called by muse, mutect2
